Somatic mutation profile of tumor specimen efc971f8-54c5-4531-a792-705ecf (aliquot efc971f8-54c5-4531-a792-705ecf_D6) from CPTAC case 04OV008, project CPTAC-2 (Other and unspecified female genital organs — Cystic, Mucinous and Serous Neoplasms). Sex at birth: female; Primary diagnosis: Serous adenocarcinoma, NOS; Tissue or organ of origin: Fallopian tube; FIGO stage: Stage IIIC.
Specimen efc971f8-54c5-4531-a792-705ecf: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 353ea05b-3184-46a2-a5b9-f5c5aacb6aaf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen cedd3881-6311-4c1d-9e9d-191243 (Blood Derived Normal), aliquot cedd3881-6311-4c1d-9e9d-191243_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e42a6612-a7a8-4eb1-aa1d-ec885496f87e

The open-access MAF lists 222 somatic variants for this specimen: 161 protein-altering or splice-affecting, 37 silent, 24 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 133, Silent 37, Intron 15, Splice Site 10, Frame Shift Del 8, RNA 4, Splice Region 3, Nonsense Mutation 3, In Frame Del 3, 5'UTR 2, 3'Flank 2, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABLIM3 | c.1858-1G>A p.X620_splice | Splice Site (SNP) | VAF 12/115 reads (10%) | catalogued as COSV100448249; called by muse, mutect2, varscan2
- ADCY6 | c.265C>A p.L89M | Missense Mutation (SNP) | VAF 60/348 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); catalogued as COSV57169787; called by muse, mutect2, varscan2
- ADGRE2 | c.721C>G p.R241G | Missense Mutation (SNP) | VAF 46/422 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as rs751834080, COSV100216508; called by muse, varscan2
- ARNTL2 | c.91C>G p.P31A | Missense Mutation (SNP) | VAF 36/189 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.196); catalogued as COSV53825350; called by muse, mutect2, varscan2
- BST2 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as COSV53089431; called by muse, mutect2, varscan2
- CLPTM1 | c.224G>C p.R75P | Missense Mutation (SNP) | VAF 28/170 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.26); catalogued as rs150314527; called by muse, mutect2, varscan2
- DNAH3 | c.10402C>A p.Q3468K | Missense Mutation (SNP) | VAF 70/286 reads (24%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as COSV54545885; called by muse, mutect2, varscan2
- EHD4 | c.1110C>G p.D370E | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); catalogued as rs1350947335; called by muse, mutect2, varscan2
- ENOX2 | c.781+1G>A p.X261_splice (on ENST00000338144 / NM_001382520.1; = p.X232_splice on NM_006375.3 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 52/206 reads (25%) | catalogued as COSV57653069; called by muse, mutect2, varscan2
- EPHB2 | c.207G>C p.Q69H | Missense Mutation (SNP) | VAF 174/266 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65864991; called by muse, mutect2, varscan2
- FGF19 | c.376A>G p.I126V | Missense Mutation (SNP) | VAF 39/145 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.021); catalogued as rs760883667; called by muse, mutect2, varscan2
- FLT1 | c.1039G>A p.V347I | Missense Mutation (SNP) | VAF 76/277 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as rs143093353; called by muse, mutect2, varscan2
- GABRB1 | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 32/171 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.043); catalogued as rs775300084, COSV54979043; called by muse, mutect2, varscan2
- GNL3L | c.1204C>A p.P402T | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV60576012; called by muse, mutect2, varscan2
- GNLY | c.107T>C p.L36P | Missense Mutation (SNP) | VAF 46/271 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as COSV55703947; called by muse, mutect2, varscan2
- GSDME | c.1198G>A p.A400T | Missense Mutation (SNP) | VAF 73/288 reads (25%) | SIFT tolerated (0.56); PolyPhen benign (0.027); catalogued as rs140321823; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IRF3 | c.950G>A p.G317E | Missense Mutation (SNP) | VAF 35/191 reads (18%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.977); catalogued as rs1469737120, COSV55862173; called by muse, mutect2, varscan2
- KIF6 | c.1126G>T p.A376S | Missense Mutation (SNP) | VAF 25/133 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.591); catalogued as COSV54675055; called by muse, mutect2, varscan2
- KIFC2 | c.1835C>G p.S612C | Missense Mutation (SNP) | VAF 33/155 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV100023806; called by muse, mutect2, varscan2
- KRTAP13-4 | c.224G>A p.C75Y | Missense Mutation (SNP) | VAF 91/322 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV100481836; called by muse, mutect2, varscan2
- MAGEL2 | c.74G>T p.R25L | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious, low confidence (0); catalogued as rs895771494; called by muse, mutect2
- MINK1 | c.1344G>T p.E448D | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.021); catalogued as rs1450718872; called by muse, mutect2, varscan2
- MORF4L1 | c.280G>A p.E94K (on ENST00000331268 / NM_206839.2; = p.E55K on NM_006791.4) | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV58705384; called by muse, mutect2, varscan2
- MPC1 | c.58G>T p.D20Y | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV100515549; called by muse, mutect2, varscan2
- NKD2 | c.330+1G>C p.X110_splice | Splice Site (SNP) | VAF 26/162 reads (16%) | catalogued as COSV56889906; called by mutect2, varscan2
- PGS1 | c.776C>T p.A259V | Missense Mutation (SNP) | VAF 131/307 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.077); catalogued as rs761581121; called by muse, mutect2, varscan2
- PHOX2B | c.92C>T p.A31V | Missense Mutation (SNP) | VAF 83/489 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV56930501; called by muse, mutect2, varscan2
- POPDC2 | c.974G>A p.R325Q | Missense Mutation (SNP) | VAF 104/293 reads (35%) | SIFT tolerated (0.38); PolyPhen benign (0.14); catalogued as rs762501897, COSV51740998; called by muse, mutect2, varscan2
- PTPN4 | c.1273C>T p.H425Y | Missense Mutation (SNP) | VAF 34/218 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.419); catalogued as COSV55298297; called by muse, mutect2, varscan2
- RAP1GAP2 | c.1688G>A p.R563H | Missense Mutation (SNP) | VAF 57/189 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as rs750434688, COSV54574764, COSV99624768; called by muse, mutect2, varscan2
- RP1 | c.2876C>T p.T959I | Missense Mutation (SNP) | VAF 48/444 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs1225877184; called by muse, mutect2, varscan2
- SH3BP5 | c.293C>A p.S98Y | Missense Mutation (SNP) | VAF 12/274 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV53746444; called by muse, mutect2
- SPAG4 | c.1255C>T p.R419C | Missense Mutation (SNP) | VAF 42/260 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769005995; called by muse, mutect2, varscan2
- SPATA31D1 | c.2123A>T p.E708V | Missense Mutation (SNP) | VAF 128/407 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.395); catalogued as COSV100782418; called by mutect2, varscan2
- TMEM202 | c.153G>C p.Q51H | Missense Mutation (SNP) | VAF 78/232 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs749327564; called by muse, mutect2, varscan2
- TNXB | c.10316G>A p.R3439H (on ENST00000647633; = p.R3192H on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 90/512 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0.018); catalogued as rs761239593; called by muse, mutect2, varscan2
- TRIM48 | c.351G>T p.K117N | Missense Mutation (SNP) | VAF 82/418 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.167); catalogued as COSV101338199; called by mutect2, varscan2
- ABCB1 | c.211G>T p.V71L | Missense Mutation (SNP) | VAF 107/358 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.589); called by muse, mutect2, varscan2
- ACOX1 | c.164C>G p.T55S | Missense Mutation (SNP) | VAF 80/518 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- APOL1 | c.969A>T p.E323D | Missense Mutation (SNP) | VAF 67/232 reads (29%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ARAP3 | c.3366A>T p.E1122D | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ASB10 | c.809C>T p.T270I (on ENST00000420175 / NM_001142459.2; = p.T255I on NM_080871.4) | Missense Mutation (SNP) | VAF 80/576 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- ASZ1 | c.1094_1097del p.K365Sfs*5 | Frame Shift Del (DEL) | VAF 12/98 reads (12%) | called by mutect2, pindel, varscan2
- BAZ2B | c.3244G>A p.G1082R | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BBS2 | c.545G>A p.G182E | Missense Mutation (SNP) | VAF 247/356 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BTNL2 | c.76_79+18delinsGAT p.X26_splice | Splice Site (DEL) | VAF 32/195 reads (16%) | called by pindel, varscan2*
- CCDC14 | c.144G>C p.E48D | Missense Mutation (SNP) | VAF 46/119 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.537); called by muse, mutect2, varscan2
- CD93 | c.472C>A p.P158T | Missense Mutation (SNP) | VAF 45/190 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.435); called by muse, mutect2, varscan2
- CDC42EP1 | c.963G>T p.W321C | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CFAP36 | c.844A>T p.K282* | Nonsense Mutation (SNP) | VAF 11/111 reads (10%) | called by muse, mutect2, varscan2
- CFAP43 | c.2374del p.S792Afs*19 | Frame Shift Del (DEL) | VAF 22/97 reads (23%) | called by mutect2, pindel, varscan2
- COL6A5 | c.5827+2T>G p.X1943_splice (on ENST00000312481; = p.X1939_splice on NM_153264.6 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 24/167 reads (14%) | called by muse, mutect2, varscan2
- CRYBA4 | c.443+2T>C p.X148_splice | Splice Site (SNP) | VAF 58/166 reads (35%) | called by muse, mutect2, varscan2
- CYLC2 | c.108A>T p.L36F | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- CYP3A4 | c.598C>A p.Q200K | Missense Mutation (SNP) | VAF 20/381 reads (5%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2
- DAAM2 | c.1721G>C p.C574S | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0.021); called by muse, mutect2
- DEK | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.066); called by muse, varscan2
- DIP2A | c.2343_2377del p.I782Gfs*6 | Frame Shift Del (DEL) | VAF 34/268 reads (13%) | called by mutect2, pindel
- DLX2 | c.214C>G p.H72D | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.361); called by muse, mutect2, varscan2
- DMD | c.8663C>A p.P2888H | Missense Mutation (SNP) | VAF 61/197 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- DMRTC2 | c.447G>C p.K149N | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- DNAH6 | c.6898_6907delinsAAGGTA p.L2300Kfs*15 | Frame Shift Del (DEL) | VAF 15/94 reads (16%) | called by pindel, varscan2*
- DNAH8 | c.12001G>T p.D4001Y | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.393); called by muse, mutect2, varscan2
- DNASE1L2 | c.266G>A p.S89N | Missense Mutation (SNP) | VAF 49/206 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- DOCK6 | c.3304C>G p.P1102A | Missense Mutation (SNP) | VAF 36/179 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.005); called by mutect2, varscan2
- DOP1B | c.3769G>A p.E1257K | Missense Mutation (SNP) | VAF 48/243 reads (20%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.655); called by muse, mutect2, varscan2
- DSG4 | c.2077G>A p.V693M | Missense Mutation (SNP) | VAF 67/312 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- EDNRB | c.922A>G p.T308A (on ENST00000377211 / NM_001201397.1; = p.T218A on NM_000115.5) | Missense Mutation (SNP) | VAF 50/221 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- EFCAB13 | c.840T>G p.F280L | Missense Mutation (SNP) | VAF 35/129 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- ELL | c.755T>C p.M252T | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- EXOC7 | c.886C>G p.L296V | Missense Mutation (SNP) | VAF 30/195 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- FAAP20 | c.453G>C p.Q151H | Missense Mutation (SNP) | VAF 29/51 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- FAM214B | c.1463+1G>A p.X488_splice | Splice Site (SNP) | VAF 37/96 reads (39%) | called by muse, mutect2, varscan2
- FAM47C | c.1690A>C p.K564Q | Missense Mutation (SNP) | VAF 40/172 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.261); called by mutect2, varscan2
- FCRLA | c.49A>T p.T17S | Missense Mutation (SNP) | VAF 26/149 reads (17%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.055); called by mutect2, varscan2
- FGF18 | c.430G>A p.A144T | Missense Mutation (SNP) | VAF 47/320 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- FKBP1B | c.130A>C p.N44H | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- FOXI3 | c.980G>C p.S327T | Missense Mutation (SNP) | VAF 115/613 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.257); called by mutect2, varscan2
- G6PD | c.340G>C p.D114H | Missense Mutation (SNP) | VAF 109/448 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.012); called by mutect2, varscan2
- GABRA4 | c.470A>T p.N157I | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- GALNT6 | c.1784G>T p.G595V | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- GLTP | c.206C>A p.T69N | Missense Mutation (SNP) | VAF 78/311 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- GLYATL2 | c.351_374del p.A118_V125del | In Frame Del (DEL) | VAF 36/160 reads (23%) | called by mutect2, pindel, varscan2
- GNG4 | c.139G>T p.A47S | Missense Mutation (SNP) | VAF 77/182 reads (42%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.698); called by muse, mutect2, varscan2
- GPRASP2 | c.172C>G p.P58A | Missense Mutation (SNP) | VAF 50/196 reads (26%) | SIFT tolerated (0.87); PolyPhen benign (0); called by muse, mutect2, varscan2
- GYPC | c.91A>G p.T31A | Missense Mutation (SNP) | VAF 106/696 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IGKV1D-43 | c.31G>T p.G11W | Missense Mutation (SNP) | VAF 60/296 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.533); called by mutect2, varscan2
- ITGAE | c.1078G>C p.D360H | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- ITGAL | c.2940C>A p.S980R | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- ITK | c.1450-2A>T p.X484_splice | Splice Site (SNP) | VAF 100/532 reads (19%) | called by mutect2, varscan2
- KCNA5 | c.1753A>G p.K585E | Missense Mutation (SNP) | VAF 115/690 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- KCNQ4 | c.315A>G p.I105M | Missense Mutation (SNP) | VAF 90/324 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- KDM1B | c.1391G>C p.R464T | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- KIF21B | c.2467A>G p.R823G | Missense Mutation (SNP) | VAF 60/268 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.419); called by muse, mutect2, varscan2
- KIFC3 | c.650T>C p.L217P | Missense Mutation (SNP) | VAF 137/587 reads (23%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- LRP4 | c.4311G>T p.W1437C | Missense Mutation (SNP) | VAF 94/388 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by mutect2, varscan2
- MAP3K20 | c.1888G>A p.V630M | Missense Mutation (SNP) | VAF 88/497 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- MAP7D3 | c.1123G>T p.E375* | Nonsense Mutation (SNP) | VAF 112/505 reads (22%) | called by muse, mutect2, varscan2
- MAPK8IP1 | c.737_770del p.A246Gfs*19 | Frame Shift Del (DEL) | VAF 75/307 reads (24%) | called by mutect2, pindel, varscan2
- MED10 | c.215A>G p.D72G | Missense Mutation (SNP) | VAF 62/189 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MSRB1 | c.-24_17del | Translation Start Site (DEL) | VAF 10/57 reads (18%) | called by mutect2, pindel, varscan2
- MUC2 | c.2009A>T p.N670I | Missense Mutation (SNP) | VAF 50/227 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.687); called by muse, mutect2, varscan2
- MVK | c.759G>T p.R253S | Missense Mutation (SNP) | VAF 84/388 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.535); called by mutect2, varscan2
- MYO18B | c.5858A>C p.E1953A | Missense Mutation (SNP) | VAF 39/129 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- N4BP2 | c.1871C>A p.S624Y | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- ODF1 | c.613T>C p.C205R | Missense Mutation (SNP) | VAF 32/242 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- OR10J3 | c.899G>C p.C300S | Missense Mutation (SNP) | VAF 54/257 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OTOL1 | c.1321G>T p.V441F | Missense Mutation (SNP) | VAF 112/384 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PACSIN3 | c.446A>G p.E149G | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.238); called by muse, mutect2, varscan2
- PAPOLA | c.263C>G p.S88C | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.699); called by muse, mutect2, varscan2
- PC | c.2336G>C p.G779A | Missense Mutation (SNP) | VAF 92/507 reads (18%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.474); called by muse, varscan2
- PCDH12 | c.242C>G p.S81C | Missense Mutation (SNP) | VAF 47/227 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- PCDHA13 | c.350del p.F117Sfs*5 | Frame Shift Del (DEL) | VAF 84/412 reads (20%) | called by mutect2, pindel, varscan2
- PCLO | c.12587_12596del p.I4196Kfs*22 | Frame Shift Del (DEL) | VAF 65/394 reads (16%) | called by mutect2, pindel, varscan2
- PDCD11 | c.3925A>C p.K1309Q | Missense Mutation (SNP) | VAF 41/160 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- PKN3 | c.1271C>G p.P424R | Missense Mutation (SNP) | VAF 70/198 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PPP4R4 | c.889T>G p.S297A | Missense Mutation (SNP) | VAF 46/189 reads (24%) | SIFT tolerated (0.45); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- PRAMEF17 | c.1089C>A p.D363E | Missense Mutation (SNP) | VAF 150/499 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.858); called by mutect2, varscan2
- PRKN | c.734+3A>T | Splice Region (SNP) | VAF 61/194 reads (31%) | called by muse, mutect2, varscan2
- PTCH2 | c.1083G>A p.Q361= | Splice Region (SNP) | VAF 183/863 reads (21%) | called by muse, mutect2, varscan2
- RAD54L2 | c.2032G>C p.A678P | Missense Mutation (SNP) | VAF 81/304 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RASAL2 | c.2864C>A p.P955Q | Missense Mutation (SNP) | VAF 42/166 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); called by mutect2, varscan2
- RCAN2 | c.261+1G>C p.X87_splice | Splice Site (SNP) | VAF 8/67 reads (12%) | called by muse, mutect2, varscan2
- RFPL2 | c.250G>C p.A84P | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- RNF123 | c.1495+1G>A p.X499_splice | Splice Site (SNP) | VAF 73/256 reads (29%) | called by muse, mutect2, varscan2
- RNFT1 | c.1152del p.K384Nfs*16 | Frame Shift Del (DEL) | VAF 7/36 reads (19%) | called by mutect2, pindel, varscan2
- RPS3A | c.664A>G p.K222E | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.317); called by muse, mutect2, varscan2
- RSL1D1 | c.1286A>C p.E429A | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- SEMA3A | c.799C>T p.Q267* | Nonsense Mutation (SNP) | VAF 23/124 reads (19%) | called by muse, varscan2
- SEMA3A | c.797G>A p.G266D | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, varscan2
- SEPTIN4 | c.452-7_452-5del | Splice Region (DEL) | VAF 19/66 reads (29%) | called by pindel, varscan2
- SKOR1 | c.1793T>A p.V598E | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- SLC15A5 | c.608A>C p.N203T | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- SLC22A14 | c.1383G>T p.E461D | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT tolerated (0.53); PolyPhen benign (0.171); called by muse, mutect2
- SLC2A6 | c.117C>A p.F39L | Missense Mutation (SNP) | VAF 45/143 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SLC4A10 | c.2089A>G p.N697D (on ENST00000446997 / NM_001354461.2; = p.N667D on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/180 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.296); called by muse, mutect2, varscan2
- SLC9A5 | c.1001C>A p.T334N | Missense Mutation (SNP) | VAF 178/318 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- SLC9C1 | c.2864A>T p.N955I | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- SMC1A | c.723_743del p.L242_E248del | In Frame Del (DEL) | VAF 44/250 reads (18%) | called by mutect2, varscan2
- SPRR1B | c.214C>T p.P72S | Missense Mutation (SNP) | VAF 58/155 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- STAB2 | c.4575C>A p.D1525E | Missense Mutation (SNP) | VAF 39/121 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.469); called by muse, mutect2, varscan2
- STAR | c.827A>T p.E276V | Missense Mutation (SNP) | VAF 115/437 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- STARD7 | c.152A>G p.E51G | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- TANGO2 | c.664A>T p.S222C | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- TAS1R2 | c.1508A>C p.Q503P | Missense Mutation (SNP) | VAF 48/128 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TDRD1 | c.883C>A p.L295I | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.858); called by mutect2, varscan2
- TERB2 | c.222T>G p.N74K | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.44); PolyPhen benign (0); called by mutect2, varscan2
- TG | c.4514T>A p.F1505Y | Missense Mutation (SNP) | VAF 104/560 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.426); called by muse, mutect2, varscan2
- TMC2 | c.2111T>G p.F704C | Missense Mutation (SNP) | VAF 49/287 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TP53 | c.442_447del p.D148_S149del | In Frame Del (DEL) | VAF 152/262 reads (58%) | called by pindel, varscan2
- TRAV19 | c.168G>T p.W56C | Missense Mutation (SNP) | VAF 70/253 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRH | c.488C>G p.A163G | Missense Mutation (SNP) | VAF 90/245 reads (37%) | SIFT tolerated (0.3); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- UBR1 | c.3850A>T p.I1284F | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- VWA3A | c.539T>A p.I180N | Missense Mutation (SNP) | VAF 55/192 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.409); called by muse, mutect2, varscan2
- WASHC1 | c.1114G>A p.A372T | Missense Mutation (SNP) | VAF 100/1092 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, varscan2
- ZBTB39 | c.695C>G p.T232S | Missense Mutation (SNP) | VAF 77/364 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZDHHC13 | c.1669A>C p.S557R | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.625); called by muse, mutect2, varscan2
- ZNF419 | c.531C>G p.H177Q | Missense Mutation (SNP) | VAF 115/260 reads (44%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- ZNF429 | c.68C>G p.T23R | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- ZNF613 | c.487T>C p.S163P (on ENST00000293471 / NM_001031721.4; = p.S127P on NM_024840.4) | Missense Mutation (SNP) | VAF 25/183 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.822); called by muse, mutect2, varscan2
- ZNF865 | c.48C>G p.S16R | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious, low confidence (0.02); called by mutect2, varscan2
- ADCY3 | c.547C>T p.L183= | Silent (SNP) | VAF 28/144 reads (19%) | called by muse, mutect2, varscan2
- ALOX5AP | c.477C>T p.L159= | Silent (SNP) | VAF 23/71 reads (32%) | called by muse, mutect2, varscan2
- ANKRD62 | c.915C>T p.C305= | Silent (SNP) | VAF 9/31 reads (29%) | called by muse, mutect2, varscan2
- ARHGAP1 | c.477C>T p.Y159= | Silent (SNP) | VAF 34/162 reads (21%) | called by muse, mutect2, varscan2
- CAND1 | c.2793C>T p.N931= | Silent (SNP) | VAF 41/160 reads (26%) | called by muse, mutect2, varscan2
- CBX2 | c.927G>A p.P309= | Silent (SNP) | VAF 62/435 reads (14%) | catalogued as rs202008143, COSV53970337; called by muse, mutect2, varscan2
- CLUH | c.66G>A p.R22= (on ENST00000435359; = p.R60= on NM_015229.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 48/165 reads (29%) | called by muse, mutect2, varscan2
- DENND1A | c.1704C>A p.I568= | Silent (SNP) | VAF 100/368 reads (27%) | called by muse, mutect2, varscan2
- GPR173 | c.1002C>T p.A334= | Silent (SNP) | VAF 84/257 reads (33%) | catalogued as rs782383431; called by muse, mutect2, varscan2
- KLHL2 | c.951A>G p.P317= | Silent (SNP) | VAF 105/176 reads (60%) | called by muse, mutect2, varscan2
- LRRC25 | c.645A>G p.L215= | Silent (SNP) | VAF 71/309 reads (23%) | catalogued as rs559303146; called by muse, mutect2, varscan2
- MBNL3 | c.511C>T p.L171= | Silent (SNP) | VAF 15/73 reads (21%) | called by muse, mutect2, varscan2
- MMP15 | c.699C>A p.T233= | Silent (SNP) | VAF 86/329 reads (26%) | called by muse, mutect2, varscan2
- NACAD | c.285C>G p.L95= | Silent (SNP) | VAF 42/192 reads (22%) | called by mutect2, varscan2
- NDUFAF1 | c.525G>A p.G175= | Silent (SNP) | VAF 25/120 reads (21%) | called by muse, mutect2, varscan2
- NELL1 | c.471C>T p.S157= | Silent (SNP) | VAF 20/80 reads (25%) | catalogued as rs200688314; called by muse, mutect2, varscan2
- NOC4L | c.75C>G p.R25= | Silent (SNP) | VAF 12/45 reads (27%) | called by muse, mutect2, varscan2
- NPHP1 | c.823C>T p.L275= | Silent (SNP) | VAF 69/419 reads (16%) | called by muse, mutect2, varscan2
- OR5AS1 | c.72A>G p.R24= | Silent (SNP) | VAF 23/102 reads (23%) | catalogued as rs1360357642; called by muse, mutect2, varscan2
- OR6C76 | c.465A>C p.P155= | Silent (SNP) | VAF 30/258 reads (12%) | catalogued as rs1381137689; called by mutect2, varscan2
- OR6J1 | c.771C>A p.I257= | Silent (SNP) | VAF 84/269 reads (31%) | called by muse, mutect2, varscan2
- PIK3C2G | c.3447G>A p.K1149= (on ENST00000676171; = p.K1108= on NM_004570.5) | Silent (SNP) | VAF 14/140 reads (10%) | called by muse, mutect2, varscan2
- PRNP | c.189T>C p.G63= | Silent (SNP) | VAF 84/398 reads (21%) | called by muse, mutect2, varscan2
- RASAL2 | c.1791G>T p.A597= | Silent (SNP) | VAF 74/279 reads (27%) | catalogued as COSV100862650; called by mutect2, varscan2
- RIPOR2 | c.2358C>G p.L786= | Silent (SNP) | VAF 18/130 reads (14%) | called by muse, mutect2, varscan2
- RNF182 | c.441T>A p.T147= | Silent (SNP) | VAF 75/511 reads (15%) | called by muse, mutect2, varscan2
- SEMA3A | c.798T>A p.G266= | Silent (SNP) | VAF 24/123 reads (20%) | catalogued as rs1470755825; called by muse, varscan2
- SIPA1L1 | c.120G>A p.R40= | Silent (SNP) | VAF 33/110 reads (30%) | catalogued as rs1251899943; called by muse, mutect2, varscan2
- SLC23A1 | c.801C>A p.L267= | Silent (SNP) | VAF 42/148 reads (28%) | catalogued as COSV62298011; called by muse, mutect2, varscan2
- SLC7A4 | c.870A>C p.L290= | Silent (SNP) | VAF 38/191 reads (20%) | catalogued as COSV60382455; called by muse, mutect2, varscan2
- SPTBN5 | c.39G>C p.G13= | Silent (SNP) | VAF 99/363 reads (27%) | called by muse, mutect2, varscan2
- SURF6 | c.424T>C p.L142= | Silent (SNP) | VAF 56/218 reads (26%) | called by muse, mutect2
- TTN | c.24672T>A p.A8224= (on ENST00000591111; = p.A7297= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/110 reads (16%) | called by muse, mutect2
- VPS13B | c.1059G>A p.V353= | Silent (SNP) | VAF 51/188 reads (27%) | catalogued as COSV100660854; called by muse, mutect2, varscan2
- WNT9A | c.624G>A p.K208= | Silent (SNP) | VAF 23/101 reads (23%) | called by muse, mutect2, varscan2
- ZNF415 | c.759T>C p.F253= | Silent (SNP) | VAF 116/270 reads (43%) | catalogued as COSV54706590; called by muse, mutect2, varscan2
- ZNF462 | c.1614G>A p.Q538= | Silent (SNP) | VAF 32/137 reads (23%) | called by muse, mutect2, varscan2
- AC068633.1 | n.227G>C | RNA (SNP) | VAF 37/147 reads (25%) | called by muse, mutect2, varscan2
- CACNA1C | c.1217+397_1217+398del | Intron (DEL) | VAF 42/442 reads (10%) | called by pindel, varscan2
- CDAN1 | c.90+21C>A | Intron (SNP) | VAF 20/79 reads (25%) | called by mutect2, varscan2
- DPP9 | c.1945-303C>T | Intron (SNP) | VAF 92/315 reads (29%) | called by muse, mutect2, varscan2
- FAM149B1 | chr10:73247461 G>A | 3'Flank (SNP) | VAF 30/163 reads (18%) | catalogued as rs1421979279; called by muse, mutect2, varscan2
- G2E3 | c.237+1173T>C | Intron (SNP) | VAF 20/82 reads (24%) | catalogued as rs1276245094; called by muse, mutect2, varscan2
- GPD1 | c.360+26G>T | Intron (SNP) | VAF 128/350 reads (37%) | called by mutect2, varscan2
- HIRA | c.*196G>C | 3'UTR (SNP) | VAF 105/315 reads (33%) | catalogued as rs782410527; called by muse, mutect2, varscan2
- LINC01164 | n.1025C>T | RNA (SNP) | VAF 44/182 reads (24%) | catalogued as rs991334562; called by muse, mutect2
- MAP4 | c.2106+42_2106+90del | Intron (DEL) | VAF 18/62 reads (29%) | called by mutect2, pindel, varscan2
- NCOA1 | c.4156-170_4156-154delinsGGG | Intron (DEL) | VAF 10/124 reads (8%) | called by pindel, varscan2*
- NFAT5 | c.1504-16C>G | Intron (SNP) | VAF 26/59 reads (44%) | called by muse, mutect2, varscan2
- OVCH1-AS1 | n.511G>A | RNA (SNP) | VAF 83/268 reads (31%) | called by muse, mutect2, varscan2
- PRDM11 | chr11:45226647 G>T | 3'Flank (SNP) | VAF 93/404 reads (23%) | called by muse, mutect2, varscan2
- PSMD13 | c.-35G>C | 5'UTR (SNP) | VAF 8/154 reads (5%) | called by muse, mutect2
- RNF212 | c.247-2611C>G | Intron (SNP) | VAF 7/33 reads (21%) | called by muse, mutect2
- SEMA4A | c.983+21A>C | Intron (SNP) | VAF 22/117 reads (19%) | called by muse, mutect2, varscan2
- SNURFL | n.219T>C | RNA (SNP) | VAF 45/293 reads (15%) | called by muse, mutect2, varscan2
- SUGCT | c.1089+2734G>T | Intron (SNP) | VAF 30/137 reads (22%) | called by muse, mutect2, varscan2
- SYP | c.227+37G>C | Intron (SNP) | VAF 77/307 reads (25%) | catalogued as COSV54295268; called by muse, mutect2, varscan2
- TBC1D8B | c.1838-708del | Intron (DEL) | VAF 4/15 reads (27%) | called by mutect2, pindel
- TFR2 | c.967-24_967-9del | Intron (DEL) | VAF 35/292 reads (12%) | called by mutect2, pindel, varscan2
- TRIM67 | c.1045-12323T>C | Intron (SNP) | VAF 56/206 reads (27%) | called by muse, mutect2, varscan2
- ZNF502 | c.-35G>T | 5'UTR (SNP) | VAF 31/127 reads (24%) | called by muse, mutect2, varscan2
